TARGET case TARGET-40-NAAWEH — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/467532ba-74a9-5d92-94cc-8dee3d2e339a

Demographics
Sex at birth: female; Race: white; Age at index: 16 years.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.9; Classification of tumor: primary; Age at diagnosis: 17.0 years (6,205 days).

Biospecimens (2 samples)
- Sample TARGET-40-NAAWEH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample TARGET-40-NAAWEH-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_and_Validation_Percent_Tumor_Supplement_20230329.xlsx (sheet OS Data), for sample TARGET-40-NAAWEH-01A-01  TS1:
- Diagnosis Confirmed: yes
- % Tumor Nuclei: Top from Biopsy: 80
- % Non Tumor Nuclei: Top from Biopsy: 20
- % Cellular Tumor: Top from Biopsy: 70
- % Normal: Top from Biopsy: 15
- % Stroma: Top from Biopsy: 0
- % Necrosis: Top from Biopsy: 15
- PASS/FAIL: pass
